Somatic mutation profile of tumor specimen TCGA-EK-A3GK-01A (aliquot TCGA-EK-A3GK-01A-11D-A20U-09) from TCGA case TCGA-EK-A3GK, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 33.4 years (12,207 days).
Specimen TCGA-EK-A3GK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9277ce12-d1b1-438c-b994-8be5d112e139.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EK-A3GK-10A (Blood Derived Normal), aliquot TCGA-EK-A3GK-10A-01D-A20U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38026dbf-1985-4a25-8c43-54af5c58717c

The open-access MAF lists 1,394 somatic variants for this specimen: 994 protein-altering or splice-affecting, 363 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 869, Silent 363, Nonsense Mutation 99, RNA 14, Splice Site 12, Intron 11, 5'UTR 7, Splice Region 6, Frame Shift Del 3, 5'Flank 3, Translation Start Site 2, 3'Flank 2.

Variants (750 of 1,394; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMPR2 | c.71C>A p.A24E | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs370120266, COSV65808844; ClinVar: pathogenic; called by muse, mutect2, varscan2
- C3orf70 | c.17C>A p.S6* | Nonsense Mutation (SNP) | VAF 11/23 reads (48%) | hotspot (GDC flag); catalogued as rs757159118, COSV58586480, COSV58587413, COSV58588338; called by muse, mutect2, varscan2
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 8/12 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MTOR | c.7255G>A p.E2419K | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587777900, COSV63869451; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- AADACL2 | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV62930188; called by muse, mutect2, varscan2
- ABCA5 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as rs1241411471, COSV67016521; called by muse, mutect2, varscan2
- ABCC1 | c.1488G>T p.K496N | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); catalogued as COSV100579563; called by muse, mutect2, varscan2
- ABCC8 | c.2635G>A p.D879N | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.227); catalogued as rs531684936, COSV56846952, COSV56857515; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCG2 | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV52944493, COSV52945379, COSV99419957; called by mutect2, varscan2
- ABHD18 | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66293677; called by muse, mutect2, varscan2
- AC011448.1 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as rs1197065682, COSV53063324; called by muse, mutect2, varscan2
- ACIN1 | c.3170C>G p.S1057* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | catalogued as COSV52982363; called by muse, mutect2, varscan2
- ACIN1 | c.2710C>T p.R904C | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs1381282818, COSV52975526; called by muse, mutect2, varscan2
- ACSL6 | c.238C>G p.Q80E (on ENST00000379240; = p.Q105E on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV57294742, COSV57297399; called by muse, mutect2, varscan2
- ADAMTS16 | c.2162G>A p.G721E | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56986324; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1801G>A p.E601K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.371); catalogued as rs1185638497, COSV54445178, COSV54448174; called by muse, mutect2
- ADAMTSL3 | c.2706G>C p.Q902H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs760315017, COSV54445187; called by muse, mutect2
- ADD1 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV53268429; called by muse, mutect2, varscan2
- ADD1 | c.502C>G p.H168D | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as COSV53266146, COSV53268447; called by muse, mutect2, varscan2
- ADGRD1 | c.938C>G p.S313W | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV55443294, COSV55443584, COSV99895751; called by muse, mutect2, varscan2
- ADGRG4 | c.8812G>A p.D2938N | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.676); catalogued as rs1431311985, COSV54954414, COSV54962817; called by muse, mutect2, varscan2
- ADGRL1 | c.1753G>C p.D585H (on ENST00000340736 / NM_001008701.3; = p.D580H on NM_014921.5) | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61564421; called by muse, mutect2, varscan2
- ADGRL3 | c.1813G>T p.D605Y (on ENST00000506720 / NM_001322402.2; = p.D537Y on NM_015236.6) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.195); catalogued as COSV72230339; called by muse, mutect2, varscan2
- ADGRL3 | c.3007G>A p.D1003N (on ENST00000506720 / NM_001322402.2; = p.D935N on NM_015236.6) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.135); catalogued as COSV72230345; called by muse, mutect2, varscan2
- ADNP | c.1612G>T p.E538* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV62425101; called by muse, mutect2, varscan2
- AFF2 | c.2309C>A p.S770Y | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as COSV53980151, COSV53986252; called by muse, mutect2, varscan2
- AGAP6 | c.1378G>T p.E460* (on ENST00000374056 / NM_001365867.1; = p.E483* on NM_001077665.2) | Nonsense Mutation (SNP) | VAF 48/193 reads (25%) | catalogued as COSV65017596; called by muse, mutect2, varscan2
- AGBL5 | c.2608G>C p.E870Q | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); catalogued as COSV64079591; called by muse, mutect2, varscan2
- AGO2 | c.1250C>A p.S417Y | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.308); catalogued as COSV55046809; called by muse, mutect2, varscan2
- AHNAK | c.5272G>C p.E1758Q | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as COSV57211441, COSV57226055; called by muse, mutect2, varscan2
- AHNAK | c.1867G>C p.E623Q | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.709); catalogued as COSV57211454, COSV57226196; called by muse, mutect2, varscan2
- AHRR | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0.135); catalogued as COSV57085090; called by muse, mutect2, varscan2
- AK7 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.22); catalogued as rs1443849404, COSV50870880; called by muse, mutect2, varscan2
- AKAP11 | c.4133C>A p.S1378* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as COSV50296086; called by muse, mutect2, varscan2
- AKAP12 | c.3643C>T p.P1215S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as COSV53573707; called by muse, mutect2, varscan2
- AKAP4 | c.1422G>A p.M474I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.176); catalogued as COSV62074241; called by muse, mutect2, varscan2
- AKAP4 | c.1104G>C p.K368N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV62074104, COSV62074246; called by muse, mutect2, varscan2
- AKAP6 | c.4427C>G p.S1476* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as COSV55211716; called by mutect2, varscan2
- ALB | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV55737604; called by muse, mutect2, varscan2
- ALDH5A1 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV62373313; called by muse, mutect2, varscan2
- ALDOB | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV100878868; called by muse, mutect2, varscan2
- ALMS1 | c.12067G>C p.E4023Q | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.095); catalogued as COSV52505415; called by muse, mutect2, varscan2
- ALOX12 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV52349449; called by muse, mutect2, varscan2
- AMPH | c.1783C>T p.Q595* | Nonsense Mutation (SNP) | VAF 23/64 reads (36%) | catalogued as COSV57740107; called by muse, mutect2, varscan2
- AMPH | c.991G>C p.E331Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100340532, COSV57740140; called by muse, mutect2, varscan2
- AMZ2 | c.542G>C p.R181T | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.617); catalogued as COSV63082795; called by muse, mutect2, varscan2
- ANK2 | c.8482G>C p.D2828H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV52157331; called by muse, mutect2, varscan2
- ANK3 | c.12778G>A p.E4260K (on ENST00000280772 / NM_001320874.2; = p.E884K on NM_001149.3) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.867); catalogued as rs1346507781, COSV55054405; called by muse, varscan2
- ANK3 | c.2723G>A p.G908E (on ENST00000280772 / NM_001320874.2; = p.G42E on NM_001149.3) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs773213347, COSV55054432, COSV55064892; called by muse, mutect2
- ANKRD24 | c.2164C>T p.Q722* | Nonsense Mutation (SNP) | VAF 17/30 reads (57%) | catalogued as COSV53669759; called by muse, mutect2, varscan2
- ANKRD44 | c.1999G>A p.D667N | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56553828; called by muse, mutect2, varscan2
- ANO10 | c.373C>G p.Q125E | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV52730491, COSV99428990; called by muse, mutect2, varscan2
- ANO7 | c.1502C>T p.S501F (on ENST00000274979; = p.S447F on NM_001370694.2) | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT tolerated (0.67); PolyPhen benign (0.018); catalogued as rs1363361434, COSV51470967; called by muse, mutect2, varscan2
- APOBR | c.1874G>C p.R625T (on ENST00000431282; = p.R634T on NM_018690.4) | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.188); catalogued as COSV60490148; called by muse, mutect2, varscan2
- APOL3 | c.112C>G p.Q38E | Missense Mutation (SNP) | VAF 9/26 reads (35%) | PolyPhen benign (0.007); catalogued as COSV62579570, COSV62580035; called by muse, mutect2, varscan2
- AR | c.1621G>C p.E541Q | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as COSV101019313, COSV65955582; called by muse, mutect2, varscan2
- ARFGEF2 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 25/86 reads (29%) | catalogued as COSV64211877; called by muse, mutect2, varscan2
- ARFGEF3 | c.3124C>T p.Q1042* | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | catalogued as COSV52455733; called by muse, mutect2, varscan2
- ARFIP2 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV54446621, COSV99601526; called by muse, mutect2, varscan2
- ARHGAP36 | c.1159C>T p.L387F | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV52265998, COSV52271083; called by muse, mutect2, varscan2
- ARHGAP4 | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 28/134 reads (21%) | catalogued as COSV100604076, COSV63131780; called by muse, mutect2, varscan2
- ARHGEF7 | c.1991C>T p.S664L (on ENST00000375741 / NM_001113511.2; = p.S486L on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54542223; called by muse, mutect2, varscan2
- ARID4B | c.3607G>C p.D1203H | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.326); catalogued as COSV51601967, COSV99050716; called by muse, mutect2, varscan2
- ARMH4 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.856); catalogued as COSV50761888; called by muse, mutect2, varscan2
- ARPP21 | c.847G>C p.E283Q | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51796011; called by muse, mutect2, varscan2
- ASAH1 | c.143G>A p.R48K | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.07); catalogued as COSV50501837; called by muse, mutect2, varscan2
- ATG2A | c.3902C>T p.S1301L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV65966503; called by muse, mutect2, varscan2
- ATP1A2 | c.493C>A p.Q165K | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as COSV63403477; called by muse, mutect2, varscan2
- ATP1A2 | c.2625C>G p.F875L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63403480, COSV63404317; called by muse, mutect2, varscan2
- ATP2B4 | c.3232G>C p.E1078Q | Missense Mutation (SNP) | VAF 57/102 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as COSV58176806; called by muse, mutect2, varscan2
- ATXN2 | c.2327C>T p.S776L (on ENST00000550104; = p.S616L on NM_002973.4) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as rs202014945, COSV101112757; called by muse, mutect2, varscan2
- AUTS2 | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.93); catalogued as rs1184884717, COSV61396619; called by muse, mutect2, varscan2
- BAIAP3 | c.58A>G p.T20A | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs1233733813, COSV60979555; called by muse, mutect2, varscan2
- BBS9 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 19/46 reads (41%) | catalogued as COSV54165384; called by muse, mutect2, varscan2
- BCAP31 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.18); catalogued as COSV100798935; called by muse, mutect2, varscan2
- BCAS1 | c.1037C>T p.S346L | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.301); catalogued as rs752495014, COSV65085414; called by muse, mutect2, varscan2
- BCL3 | c.1252C>G p.P418A | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.173); catalogued as COSV99378136; called by muse, mutect2
- BCL9 | c.3565G>C p.D1189H | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.443); catalogued as COSV52343335; called by muse, mutect2, varscan2
- BCORL1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV54394803; called by muse, mutect2, varscan2
- BGN | c.334G>T p.G112C | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100525187; called by muse, mutect2
- BICC1 | c.2429G>T p.G810V | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54063283; called by muse, mutect2, varscan2
- BLK | c.1249G>C p.D417H | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52053562, COSV99377208; called by muse, mutect2
- BMERB1 | c.357G>T p.K119N | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.868); catalogued as COSV55507731; called by muse, mutect2, varscan2
- BRAP | c.415C>G p.H139D | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV58155901; called by muse, mutect2, varscan2
- BRCA1 | c.1543G>C p.E515Q | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100524285, COSV58784706, COSV58788589; called by muse, mutect2, varscan2
- BRDT | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV62864542; called by muse, mutect2
- BSN | c.11518G>A p.E3840K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); catalogued as COSV56516544; called by muse, mutect2, varscan2
- BZW2 | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV51754844; called by muse, mutect2, varscan2
- C12orf56 | c.1642C>G p.Q548E (on ENST00000543942 / NM_001170633.2; = p.Q388E on NM_001099676.3) | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.38); PolyPhen benign (0.215); catalogued as COSV61486604; called by muse, mutect2, varscan2
- C16orf71 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs781229791, COSV58508683; called by muse, mutect2, varscan2
- C16orf74 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.759); catalogued as rs1199994215, COSV52456302; called by muse, mutect2, varscan2
- C1GALT1C1 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.148); catalogued as rs936090662, COSV58974028; called by muse, mutect2, varscan2
- C1QTNF2 | c.856C>G p.L286V (on ENST00000393975; = p.L241V on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67432632; called by muse, mutect2, varscan2
- C1R | c.2038G>T p.D680Y (on ENST00000536053 / NM_001354346.2; = p.D666Y on NM_001733.7) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV73382924; called by muse, mutect2, varscan2
- C1RL | c.1141G>C p.E381Q | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.117); catalogued as rs758559770, COSV56924799; called by muse, mutect2, varscan2
- C3 | c.4794G>C p.E1598D | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs768057515, COSV104368749, COSV55571883; called by muse, mutect2, varscan2
- C6 | c.1075G>C p.D359H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54708278; called by muse, mutect2, varscan2
- C7 | c.680C>A p.S227Y | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.543); catalogued as COSV57473540; called by muse, mutect2, varscan2
- C8orf58 | c.1052C>T p.S351L (on ENST00000289989 / NM_001013842.3; = p.S343L on NM_173686.3) | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV51515102; called by muse, mutect2, varscan2
- C9orf131 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.313); catalogued as COSV56610699; called by muse, mutect2, varscan2
- CABIN1 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV54080823; called by muse, mutect2, varscan2
- CACNA1F | c.3256G>A p.E1086K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59904093; called by muse, mutect2, varscan2
- CADPS | c.594G>C p.Q198H | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); catalogued as COSV51876331; called by muse, mutect2, varscan2
- CALHM6 | c.99C>G p.I33M | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV63991513; called by muse, mutect2
- CAP1 | c.1198C>G p.Q400E | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61223245; called by muse, mutect2, varscan2
- CAPN1 | c.824C>G p.S275C | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54198134; called by muse, mutect2, varscan2
- CAPN1 | c.1461C>A p.F487L | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV54198155, COSV99658915; called by muse, mutect2, varscan2
- CAPSL | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1386831632; called by muse, mutect2
- CASP8AP2 | c.4357G>A p.D1453N | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52746508; called by muse, mutect2, varscan2
- CATSPERB | c.2344G>C p.D782H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56425316; called by muse, mutect2
- CATSPERE | c.2206C>T p.Q736* | Nonsense Mutation (SNP) | VAF 18/36 reads (50%) | catalogued as COSV63675810, COSV63680739; called by muse, mutect2, varscan2
- CAVIN2 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.741); catalogued as rs765261157, COSV58424796; called by muse, mutect2
- CBWD3 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 4/91 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV64132696; called by muse, mutect2
- CBX7 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as rs1280184461, COSV53358886, COSV99334154; called by muse, mutect2, varscan2
- CCDC116 | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.482); catalogued as COSV53040303; called by muse, mutect2, varscan2
- CCDC120 | c.656C>G p.S219* | Nonsense Mutation (SNP) | VAF 33/67 reads (49%) | catalogued as COSV64515079, COSV64515908; called by muse, mutect2, varscan2
- CCDC150 | c.3169G>A p.E1057K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs949219749, COSV55873772, COSV55873921; called by muse, mutect2, varscan2
- CCDC183 | c.61C>G p.Q21E | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1418809173, COSV51566880, COSV51567474; called by muse, mutect2, varscan2
- CCDC3 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.202); catalogued as rs368910799; called by muse, mutect2, varscan2
- CCDC33 | c.1558G>C p.E520Q | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51499768; called by muse, mutect2, varscan2
- CCDC57 | c.2683C>T p.H895Y | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV60753456; called by muse, mutect2, varscan2
- CCDC60 | c.1186G>C p.E396Q | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59542983; called by muse, mutect2, varscan2
- CCT6B | c.892G>C p.D298H | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58488770; called by muse, mutect2, varscan2
- CCZ1B | c.562G>T p.D188Y | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57437026; called by muse, mutect2, varscan2
- CDC42BPA | c.2528C>T p.S843F | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV62009557; called by muse, mutect2, varscan2
- CDH17 | c.1593C>G p.F531L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV50327687, COSV50343867; called by muse, mutect2, varscan2
- CDH23 | c.6268C>G p.Q2090E | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.168); catalogued as COSV56459056; called by muse, mutect2, varscan2
- CDHR5 | c.1499C>T p.S500F (on ENST00000358353 / NM_001171968.2; = p.S506F on NM_021924.5) | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as COSV57642467; called by muse, mutect2, varscan2
- CDK13 | c.2686G>T p.D896Y | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99475528; called by muse, mutect2
- CENPE | c.1855G>A p.D619N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.815); catalogued as COSV54380148; called by muse, mutect2, varscan2
- CENPJ | c.2881G>A p.E961K | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV101121513, COSV67884315; called by muse, mutect2
- CEP164 | c.2741G>A p.R914Q | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs550799764, COSV54040365; called by muse, mutect2, varscan2
- CFAP221 | c.1108G>T p.E370* | Nonsense Mutation (SNP) | VAF 16/33 reads (48%) | catalogued as COSV54656647, COSV99732292; called by muse, mutect2, varscan2
- CFAP43 | c.250G>C p.D84H | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53377560; called by muse, mutect2, varscan2
- CFAP65 | c.5410G>A p.E1804K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.16); catalogued as rs111416503; called by muse, mutect2, varscan2
- CFH | c.3592G>A p.E1198K | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.069); catalogued as CM060895, CM070672, COSV66407688; called by muse, mutect2, varscan2
- CHCHD2 | c.43C>G p.P15A | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV68169934; called by muse, mutect2
- CHCHD3 | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 11/12 reads (92%) | catalogued as COSV52773425, COSV52782995; called by muse, mutect2, varscan2
- CHD6 | c.7217G>C p.R2406T | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV64690043; called by muse, mutect2, varscan2
- CHGA | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 16/30 reads (53%) | catalogued as COSV53662969; called by muse, mutect2, varscan2
- CHGB | c.2013G>C p.E671D | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV66760243; called by muse, mutect2, varscan2
- CHIA | c.226C>G p.L76V | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); catalogued as COSV58474881, COSV58477113; called by muse, mutect2, varscan2
- CHIT1 | c.1155G>C p.L385= | Splice Region (SNP) | VAF 34/90 reads (38%) | catalogued as COSV55146587; called by muse, mutect2, varscan2
- CHRAC1 | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as COSV55269914; called by muse, mutect2, varscan2
- CIC | c.1453G>C p.E485Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.143); catalogued as COSV50556433, COSV50560972; called by muse, mutect2, varscan2
- CIDEB | c.369G>C p.E123D | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV99350716; called by muse, mutect2
- CKAP2 | c.100C>G p.L34V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV51621740; called by muse, mutect2, varscan2
- CKAP4 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1565948554, COSV65172379; called by muse, mutect2, varscan2
- CLK4 | c.1324G>A p.D442N | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as COSV60318455; called by muse, mutect2, varscan2
- CLTC | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52247020; called by muse, mutect2, varscan2
- CMIP | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV73397694; called by muse, mutect2, varscan2
- CNGA4 | c.1501G>C p.D501H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV66005750; called by mutect2, varscan2
- CNGB1 | c.1255G>C p.E419Q | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV51900013; called by muse, mutect2
- CNTD1 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 21/62 reads (34%) | catalogued as COSV59311880; called by muse, mutect2, varscan2
- CNTN5 | c.514C>T p.Q172* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as COSV54304334; called by muse, mutect2, varscan2
- COL11A2 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 66/80 reads (83%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); catalogued as rs1299327368, COSV59496077; called by muse, mutect2, varscan2
- COL12A1 | c.7553C>T p.S2518L | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.643); catalogued as COSV59394361; called by muse, mutect2, varscan2
- COL18A1 | c.4387G>C p.E1463Q (on ENST00000359759 / NM_130444.3; = p.E1228Q on NM_030582.4) | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs201265799, COSV60588234; called by muse, varscan2
- COL18A1 | c.4440G>C p.Q1480H (on ENST00000359759 / NM_130444.3; = p.Q1245H on NM_030582.4) | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.203); catalogued as COSV60588245; called by muse, varscan2
- COL24A1 | c.549G>C p.K183N | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV65305179; called by muse, mutect2, varscan2
- COL4A1 | c.3946C>T p.Q1316* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as CM113806, COSV65424512; called by muse, mutect2
- COL6A3 | c.7988G>C p.R2663T | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55087184; called by muse, mutect2, varscan2
- COL7A1 | c.4777G>C p.D1593H | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60394466; called by muse, varscan2
- COLGALT1 | c.596C>G p.S199C | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53108579; called by muse, mutect2, varscan2
- COLGALT2 | c.671G>A p.W224* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV62299107; called by muse, mutect2
- CPLANE1 | c.8681G>C p.R2894T | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV57058027, COSV99949320; called by muse, mutect2, varscan2
- CPSF1 | c.2258C>T p.S753F | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.336); catalogued as COSV58233325; called by muse, mutect2, varscan2
- CPSF2 | c.794C>T p.S265L | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); catalogued as COSV54098009; called by muse, mutect2, varscan2
- CRACR2A | c.910G>T p.E304* | Nonsense Mutation (SNP) | VAF 25/55 reads (45%) | catalogued as COSV52912094, COSV52918103; called by muse, mutect2, varscan2
- CRB2 | c.1523G>C p.R508T | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV63502818; called by muse, mutect2, varscan2
- CRHR2 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as COSV59264864; called by muse, mutect2, varscan2
- CRLF3 | c.1207C>T p.R403* | Nonsense Mutation (SNP) | VAF 19/42 reads (45%) | catalogued as COSV60835530; called by muse, mutect2, varscan2
- CRTAC1 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV54000579; called by muse, mutect2, varscan2
- CRYL1 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs1009566194, COSV53417876; called by muse, mutect2, varscan2
- CRYM | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99561772; called by muse, mutect2, varscan2
- CSMD1 | c.3945G>T p.K1315N (on ENST00000520002; = p.K1314N on NM_033225.6) | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.082); catalogued as rs747667934, COSV59313019; called by muse, mutect2, varscan2
- CSMD2 | c.5867G>A p.R1956Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1191760345, COSV53904866; called by muse, mutect2, varscan2
- CSMD3 | c.9600G>T p.Q3200H (on ENST00000297405 / NM_001363185.1; = p.Q3031H on NM_052900.3) | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV52160070; called by muse, mutect2, varscan2
- CSMD3 | c.600C>G p.I200M | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as rs1338069090, COSV52160115, COSV52314832; called by muse, mutect2, varscan2
- CSPG4 | c.4981G>A p.E1661K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1353010988, COSV57893985; called by muse, mutect2, varscan2
- CSPG5 | c.1168G>T p.V390L | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.119); catalogued as COSV53130864; called by muse, mutect2, varscan2
- CSTF2 | c.138-1G>C p.X46_splice | Splice Site (SNP) | VAF 28/63 reads (44%) | catalogued as COSV63376215; called by muse, mutect2, varscan2
- CT55 | c.492C>G p.I164M | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.367); catalogued as COSV52277610; called by muse, mutect2, varscan2
- CTBP1 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.41); catalogued as COSV52073427; called by muse, mutect2, varscan2
- CTBP2 | c.705G>C p.Q235H | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV100456908, COSV58333830; called by muse, mutect2, varscan2
- CTSS | c.919G>C p.E307Q | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV64566215; called by muse, mutect2, varscan2
- CWH43 | c.652C>G p.L218V | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT tolerated (0.31); PolyPhen benign (0.05); catalogued as COSV56938174; called by muse, mutect2, varscan2
- CXorf56 | c.23C>G p.S8* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as COSV57438108; called by muse, mutect2
- CYP4A22 | c.597G>C p.K199N | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV53738611, COSV53739686; called by muse, mutect2, varscan2
- CYTH3 | c.1116G>A p.W372* (on ENST00000396741; = p.W371* on NM_004227.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV60359518; called by muse, varscan2
- CYTH3 | c.1057G>A p.E353K (on ENST00000396741; = p.E352K on NM_004227.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.632); catalogued as COSV60359524; called by muse, varscan2
- DAGLB | c.32G>A p.W11* | Nonsense Mutation (SNP) | VAF 23/47 reads (49%) | catalogued as COSV51703428; called by muse, mutect2, varscan2
- DAZL | c.692C>G p.S231* | Nonsense Mutation (SNP) | VAF 47/111 reads (42%) | catalogued as COSV51712572; called by muse, mutect2, varscan2
- DCHS1 | c.1654G>T p.D552Y | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55033999, COSV55034357; called by muse, mutect2, varscan2
- DCUN1D5 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.259); catalogued as COSV52784378; called by muse, mutect2, varscan2
- DDX19B | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55363738; called by muse, mutect2, varscan2
- DDX5 | c.1195G>T p.D399Y | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56748879; called by muse, mutect2, varscan2
- DEFB110 | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67018060; called by muse, mutect2, varscan2
- DENND6A | c.1424G>C p.R475T | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as COSV60767386, COSV60768379; called by muse, mutect2, varscan2
- DGAT1 | c.1232C>T p.S411L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs573410614, COSV60046776; called by muse, mutect2, varscan2
- DGCR8 | c.1856C>T p.S619F | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61226439; called by muse, mutect2, varscan2
- DGKK | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); catalogued as rs782720256, COSV65707161, COSV65708645; called by muse, mutect2, varscan2
- DHH | c.1080G>C p.L360F | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as COSV57201813; called by muse, mutect2, varscan2
- DHTKD1 | c.1117C>G p.P373A | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV53803058; called by muse, mutect2, varscan2
- DHTKD1 | c.2338C>A p.Q780K | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV53803067, COSV53803241; called by muse, mutect2, varscan2
- DHX37 | c.2514G>T p.Q838H | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.178); catalogued as rs1460330898, COSV58133861, COSV58139554; called by muse, mutect2, varscan2
- DHX8 | c.1749C>G p.I583M | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as COSV52252914, COSV99292581; called by muse, mutect2, varscan2
- DHX8 | c.2149T>C p.S717P | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52252925; called by muse, mutect2, varscan2
- DHX8 | c.2150C>T p.S717L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52252935; called by muse, mutect2, varscan2
- DIDO1 | c.3101+2T>A p.X1034_splice | Splice Site (SNP) | VAF 53/83 reads (64%) | catalogued as COSV56620032; called by muse, mutect2, varscan2
- DIP2A | c.2599G>T p.E867* | Nonsense Mutation (SNP) | VAF 23/51 reads (45%) | catalogued as COSV59476367; called by muse, mutect2, varscan2
- DIRAS3 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs898799980, COSV63970667; called by muse, mutect2, varscan2
- DLG4 | c.1556C>G p.S519W (on ENST00000399506 / NM_001321075.3; = p.S562W on NM_001365.4) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.506); catalogued as COSV57237905; called by muse, mutect2, varscan2
- DLGAP4 | c.2506G>A p.E836K (on ENST00000339266 / NM_001365621.1; = p.E833K on NM_014902.6) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV59417058; called by muse, mutect2
- DLX4 | c.712C>T p.Q238* (on ENST00000240306 / NM_138281.3; = p.Q166* on NM_001934.3) | Nonsense Mutation (SNP) | VAF 26/70 reads (37%) | catalogued as COSV53591481; called by muse, mutect2, varscan2
- DMXL2 | c.6919G>A p.E2307K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV51844757; called by muse, mutect2, varscan2
- DNAH1 | c.7453G>A p.D2485N | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV70228355; called by muse, mutect2, varscan2
- DNASE1L1 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1457884365, COSV50010017; called by muse, mutect2, varscan2
- DNMT3L | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV54263885; called by muse, mutect2, varscan2
- DOK6 | c.290-1G>A p.X97_splice | Splice Site (SNP) | VAF 22/55 reads (40%) | catalogued as rs1191838037, COSV66929858; called by muse, mutect2, varscan2
- DPYD | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.593); catalogued as rs763862486, COSV64595593; called by muse, mutect2, varscan2
- DSC1 | c.2572C>G p.L858V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57144658, COSV99938230; called by muse, mutect2, varscan2
- DTX1 | c.1190G>T p.R397L | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV57496999; called by muse, mutect2, varscan2
- DUOX1 | c.1481G>A p.G494E | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58479751; called by muse, mutect2, varscan2
- DYNC1LI1 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.045); catalogued as COSV56127329; called by mutect2, varscan2
- DZIP1L | c.1774C>G p.P592A | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.505); catalogued as COSV59520301; called by muse, mutect2, varscan2
- DZIP3 | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV64311817; called by muse, mutect2, varscan2
- EDEM3 | c.1989G>C p.L663F | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.609); catalogued as COSV58923753; called by muse, mutect2, varscan2
- EEF1A1 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.609); catalogued as COSV58549416, COSV58550657; called by muse, mutect2, varscan2
- EEF1A1 | c.213C>G p.I71M | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV58549422, COSV58549546; called by muse, mutect2, varscan2
- EEF1A1 | c.79C>G p.L27V | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV58549430; called by muse, mutect2, varscan2
- EGFLAM | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.174); catalogued as rs1401024420, COSV59299398; called by muse, mutect2, varscan2
- EGFLAM | c.1992C>G p.I664M | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV59299421; called by muse, mutect2, varscan2
- EHMT1 | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV58374164; called by muse, mutect2, varscan2
- EIF2AK1 | c.1348C>T p.L450F | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV52238610; called by muse, mutect2, varscan2
- EIF2AK2 | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV51795976; called by muse, mutect2, varscan2
- EIF4E3 | c.330G>C p.E110D (on ENST00000425534 / NM_001134651.2; = p.E4D on NM_173359.5) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.166); catalogued as COSV55203834; called by muse, mutect2, varscan2
- EIF4G3 | c.3669G>C p.E1223D | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV51680376; called by muse, mutect2, varscan2
- ELF3 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs745722163, COSV62838007; called by muse, mutect2, varscan2
- ELMO1 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV60299879, COSV60302276; called by muse, mutect2, varscan2
- ELMO2 | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.061); catalogued as COSV51682140; called by muse, mutect2, varscan2
- ELOA2 | c.1859G>C p.R620T | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.595); catalogued as COSV55297755; called by muse, mutect2, varscan2
- ENDOD1 | c.1152C>G p.I384M | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.1); catalogued as COSV53589330; called by muse, mutect2, varscan2
- ENPP1 | c.2488C>T p.H830Y | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62931905; called by muse, mutect2, varscan2
- ENPP6 | c.107C>G p.S36* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV57067494; called by muse, mutect2, varscan2
- EP300 | c.6643C>T p.Q2215* | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | catalogued as COSV54331285, COSV54339679; called by muse, mutect2, varscan2
- EPS8 | c.1793C>T p.A598V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV55529832; called by mutect2, varscan2
- ERAL1 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1309034147, COSV54739743; called by muse, mutect2, varscan2
- ERBB2 | c.3235G>A p.E1079K | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.91); PolyPhen benign (0.178); catalogued as rs1038581447, COSV54068585; called by muse, mutect2
- ERBB3 | c.2031G>A p.M677I | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV57251379, COSV57263696; called by muse, mutect2, varscan2
- ERMARD | c.1743C>G p.I581M | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.123); catalogued as COSV64647990; called by muse, mutect2, varscan2
- ESYT2 | c.889C>T p.H297Y (on ENST00000613624; = p.H221Y on NM_020728.3) | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); catalogued as COSV51750314; called by muse, mutect2, varscan2
- ESYT3 | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 25/85 reads (29%) | catalogued as COSV56680234; called by muse, mutect2, varscan2
- EXOG | c.962C>G p.S321* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as COSV55063166; called by mutect2, varscan2
- EYA2 | c.150C>G p.F50L | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV57941856; called by muse, mutect2, varscan2
- EZR | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.217); catalogued as COSV61453485; called by muse, mutect2, varscan2
- F5 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs752636369, COSV63123123; called by muse, mutect2, varscan2
- F8A1 | c.910G>C p.D304H | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV57704965; called by mutect2, varscan2
- FAM111B | c.962G>A p.R321K | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as COSV59111718, COSV59112188; called by muse, mutect2, varscan2
- FAM13A | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.194); catalogued as COSV52001308; called by muse, mutect2, varscan2
- FAM13A | c.1444C>T p.Q482* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as COSV52001331; called by muse, mutect2, varscan2
- FAM168B | c.163C>G p.P55A | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.05); catalogued as COSV66303959; called by muse, mutect2, varscan2
- FAM193A | c.2725G>A p.D909N | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV61193254; called by muse, mutect2, varscan2
- FAM204A | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV64987648; called by muse, mutect2, varscan2
- FAM210A | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as COSV59184056; called by muse, mutect2, varscan2
- FAM217B | c.1101G>C p.E367D | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.136); catalogued as COSV62564181, COSV62564244; called by muse, mutect2, varscan2
- FAM234A | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV56993847; called by muse, mutect2, varscan2
- FAM24A | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.047); catalogued as COSV64405899; called by muse, mutect2, varscan2
- FAM47C | c.952C>T p.L318F | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as COSV63726059; called by muse, mutect2, varscan2
- FAM71D | c.1206C>G p.I402M | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.233); catalogued as COSV61295267; called by muse, mutect2, varscan2
- FANCL | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV52074013; called by mutect2, varscan2
- FARP2 | c.2565G>C p.K855N | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as rs917540877, COSV50870651; called by muse, mutect2, varscan2
- FASN | c.5248G>A p.E1750K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs1464240266, COSV60753431; called by muse, mutect2, varscan2
- FBXO38 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57027207; called by muse, mutect2, varscan2
- FBXO38 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV57027217; called by mutect2, varscan2
- FBXO42 | c.1689C>G p.I563M | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); catalogued as COSV65045389; called by muse, mutect2
- FDFT1 | c.1043G>C p.R348T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV55042156; called by muse, mutect2
- FEM1B | c.1092C>G p.I364M | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.494); catalogued as COSV100183656; called by muse, mutect2, varscan2
- FGA | c.2187G>C p.E729D | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs1289107077, COSV57395199; called by muse, mutect2, varscan2
- FGD1 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.143); catalogued as COSV64308553; called by muse, mutect2, varscan2
- FGF4 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV51449835; called by muse, mutect2, varscan2
- FKBP10 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.8); PolyPhen benign (0.234); catalogued as rs142507953; called by muse, mutect2, varscan2
- FLNB | c.2716C>T p.H906Y | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs1290855363, COSV55875664; called by muse, mutect2, varscan2
- FLNC | c.5234C>G p.S1745C | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV57954674, COSV57956863; called by muse, mutect2, varscan2
- FLOT2 | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV67528992; called by muse, mutect2, varscan2
- FLT3 | c.369-1G>A p.X123_splice | Splice Site (SNP) | VAF 14/35 reads (40%) | catalogued as COSV54050971; called by muse, mutect2, varscan2
- FMN2 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.038); catalogued as COSV60427537; called by muse, mutect2, varscan2
- FMNL3 | c.292-2A>C p.X98_splice | Splice Site (SNP) | VAF 7/17 reads (41%) | catalogued as COSV53300980; called by muse, mutect2, varscan2
- FMO5 | c.1485C>G p.I495M | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.547); catalogued as COSV54205910; called by muse, mutect2, varscan2
- FMR1 | c.694C>G p.L232V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54423336; called by muse, mutect2, varscan2
- FN1 | c.5431C>G p.L1811V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.51); catalogued as COSV60551277; called by muse, mutect2, varscan2
- FNBP1 | c.1411G>C p.E471Q | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100852733, COSV63086631; called by muse, mutect2, varscan2
- FOCAD | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as COSV58097548; called by muse, mutect2, varscan2
- FOXO4 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as COSV58575141; called by muse, mutect2, varscan2
- FOXR2 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100189431, COSV59258289; called by muse, mutect2, varscan2
- FPGT | c.1015G>C p.E339Q | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as COSV63838540; called by muse, mutect2, varscan2
- FRA10AC1 | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.043); catalogued as COSV63271609, COSV63273384; called by muse, mutect2, varscan2
- FRMD1 | c.1234G>C p.E412Q | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV99349770; called by muse, mutect2
- FRY | c.8560G>A p.E2854K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.095); catalogued as rs749157630, COSV66511155; called by muse, mutect2, varscan2
- FUCA2 | c.1266G>A p.V422= | Splice Region (SNP) | VAF 4/10 reads (40%) | catalogued as COSV50020017; called by muse, varscan2
- FYCO1 | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56115384; called by muse, mutect2, varscan2
- GALNT17 | c.1146G>C p.K382N | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.119); catalogued as COSV104413569, COSV61150856, COSV61158762; called by muse, mutect2
- GANAB | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as COSV60464016; called by muse, mutect2, varscan2
- GAREM1 | c.2506G>A p.E836K (on ENST00000269209 / NM_001242409.2; = p.E835K on NM_022751.3) | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52508428; called by muse, mutect2, varscan2
- GARNL3 | c.1796G>C p.R599T | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as COSV59225608, COSV59228105; called by muse, mutect2, varscan2
- GARNL3 | c.2908G>A p.E970K | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.935); catalogued as rs371069399; called by muse, mutect2, varscan2
- GCM2 | c.512G>A p.R171K | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65275438; called by muse, mutect2, varscan2
- GDA | c.148C>G p.Q50E | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV52992313; called by muse, mutect2, varscan2
- GDF11 | c.252G>C p.L84F | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57689581; called by muse, mutect2, varscan2
- GIPR | c.536C>G p.S179C | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54423641; called by muse, mutect2, varscan2
- GJA10 | c.844C>G p.P282A | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV65355093; called by muse, mutect2, varscan2
- GLRB | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52415986, COSV52419291; called by muse, mutect2, varscan2
- GLT8D2 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.033); catalogued as rs775838336, COSV62561704; called by muse, mutect2, varscan2
- GOLGB1 | c.8095G>A p.E2699K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61464946; called by muse, mutect2, varscan2
- GON4L | c.5471C>G p.S1824* | Nonsense Mutation (SNP) | VAF 11/66 reads (17%) | catalogued as COSV99674304; called by muse, mutect2, varscan2
- GP2 | c.589G>A p.E197K (on ENST00000381362 / NM_001007240.3; = p.E194K on NM_001502.4) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.368); catalogued as rs530327819, COSV56893154, COSV56895292; called by muse, mutect2, varscan2
- GPAM | c.2248G>A p.E750K | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.321); catalogued as COSV62080871; called by muse, mutect2, varscan2
- GPATCH8 | c.1796C>G p.S599* | Nonsense Mutation (SNP) | VAF 42/173 reads (24%) | catalogued as COSV59194445; called by muse, mutect2, varscan2
- GPATCH8 | c.704C>G p.S235* | Nonsense Mutation (SNP) | VAF 17/58 reads (29%) | catalogued as COSV100132510, COSV59194454; called by muse, mutect2, varscan2
- GPR161 | c.566C>T p.T189M | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371919925; called by muse, mutect2, varscan2
- GPRIN2 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.555); catalogued as rs781935336, COSV65400870; called by muse, mutect2, varscan2
- GPS1 | c.1309G>C p.E437Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.178); catalogued as COSV57648681; called by muse, mutect2
- GRIA1 | c.2453G>T p.G818V | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT tolerated (0.79); PolyPhen benign (0.209); catalogued as COSV53599512, COSV53607450; called by muse, mutect2, varscan2
- GRIN3A | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as rs962619066, COSV62452826; called by muse, mutect2, varscan2
- GRK1 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.226); catalogued as rs376631949; called by muse, mutect2
- GRM2 | c.2390C>T p.S797L | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV56584487; called by muse, mutect2, varscan2
- GRN | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.129); catalogued as COSV50006898; called by muse, mutect2, varscan2
- GRSF1 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.446); catalogued as rs775900058, COSV54655106; called by muse, mutect2, varscan2
- GSTM2 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV53982240; called by muse, mutect2, varscan2
- GTF2A1 | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as rs1196969592, COSV53336888; called by muse, mutect2, varscan2
- GTF3C1 | c.5542G>A p.E1848K | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.1); catalogued as rs750603013, COSV62240609; called by muse, mutect2, varscan2
- GTF3C2 | c.2068G>C p.D690H | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53126149; called by muse, mutect2
- GTF3C4 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1184003543, COSV64644955; called by muse, mutect2, varscan2
- GUCY2D | c.2368G>C p.E790Q | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54695851; called by muse, mutect2, varscan2
- GYS1 | c.1261G>C p.D421H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs763908374, COSV54402440, COSV54404681; called by mutect2, varscan2
- H1-4 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 37/43 reads (86%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.714); catalogued as COSV56800756; called by muse, mutect2, varscan2
- H2AC4 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52518518, COSV52519334; called by muse, mutect2, varscan2
- HEATR1 | c.2342T>A p.V781E | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs528453790, COSV63980786; called by muse, mutect2, varscan2
- HEATR1 | c.1357G>T p.D453Y | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as COSV63980790, COSV63983016; called by muse, mutect2, varscan2
- HEATR4 | c.2023G>A p.D675N | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58571731; called by muse, mutect2, varscan2
- HECTD2 | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.096); catalogued as COSV53220446; called by muse, mutect2, varscan2
- HECTD3 | c.2242G>C p.E748Q | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as COSV64670053; called by muse, mutect2, varscan2
- HECTD3 | c.1957G>C p.E653Q | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV64670065; called by muse, varscan2
- HELQ | c.2401G>A p.E801K | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV55024939; called by muse, mutect2, varscan2
- HEMK1 | c.490C>G p.L164V | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51750387; called by muse, mutect2, varscan2
- HEPH | c.1823C>T p.S608L (on ENST00000343002; = p.S341L on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV57959782; called by muse, mutect2, varscan2
- HERC5 | c.2636C>T p.A879V | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs773827213, COSV52042202; called by muse, mutect2, varscan2
- HERC5 | c.2828C>G p.A943G | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52039262; called by muse, mutect2, varscan2
- HERPUD2 | c.865C>T p.L289F | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.944); catalogued as COSV60944840; called by muse, mutect2, varscan2
- HEXIM1 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs903988968, COSV100203564, COSV60176961; called by muse, mutect2, varscan2
- HFM1 | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs775085469, COSV54025908; called by muse, mutect2, varscan2
- HGF | c.126C>A p.F42L | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.29); catalogued as COSV55948253; called by muse, mutect2, varscan2
- HIBCH | c.696G>C p.L232F | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as COSV62891387; called by muse, mutect2, varscan2
- HIVEP1 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.12); PolyPhen benign (0.27); catalogued as COSV65100291, COSV65100691; called by muse, mutect2, varscan2
- HIVEP2 | c.6593G>A p.G2198D | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.086); catalogued as COSV50009470; called by muse, mutect2, varscan2
- HLTF | c.2678C>G p.S893* | Nonsense Mutation (SNP) | VAF 9/17 reads (53%) | catalogued as COSV59500157; called by muse, mutect2, varscan2
- HNRNPA1 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.41); catalogued as COSV52936531, COSV52936536; called by muse, varscan2
- HOMEZ | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as COSV62536866; called by muse, mutect2, varscan2
- HOOK3 | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV56881664, COSV56887352; called by muse, mutect2, varscan2
- HPCAL4 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65716211; called by muse, mutect2, varscan2
- HPGDS | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54773839; called by muse, mutect2, varscan2
- HRG | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as rs529521530, COSV51644141; called by muse, mutect2, varscan2
- HRNR | c.5545G>A p.G1849R | Missense Mutation (SNP) | VAF 41/404 reads (10%) | SIFT tolerated (0.82); PolyPhen benign (0.1); catalogued as rs769433525, COSV64257078; called by muse, mutect2, varscan2
- HSD17B14 | c.797C>G p.P266R | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.149); catalogued as COSV54412631, COSV54413168; called by muse, mutect2, varscan2
- HSDL2 | c.1237C>G p.Q413E | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.108); catalogued as COSV52714601; called by muse, mutect2
- HSP90AB1 | c.87C>G p.I29M | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV62334192; called by muse, mutect2, varscan2
- HYAL2 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as COSV63306135; called by muse, mutect2, varscan2
- IDH3G | c.1064C>T p.S355F | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV54207166; called by muse, mutect2, varscan2
- IFT172 | c.3301G>A p.E1101K | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV53132716; called by muse, mutect2, varscan2
- IFT57 | c.22G>C p.V8L | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.022); catalogued as COSV99197543; called by muse, mutect2
- IGDCC3 | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as rs761189945, COSV60077331; called by muse, mutect2, varscan2
- IGF2R | c.1875G>C p.E625D | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV63628428; called by muse, mutect2, varscan2
- IGSF1 | c.3086C>G p.S1029C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63837104; called by muse, mutect2, varscan2
- IL16 | c.1709C>T p.P570L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.04); catalogued as COSV57262698; called by muse, mutect2, varscan2
- ILF2 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.392); catalogued as rs768322800, COSV62627198; called by muse, mutect2, varscan2
- INO80 | c.2237G>C p.R746T | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62737575; called by muse, mutect2, varscan2
- INPP4A | c.2378G>A p.R793Q (on ENST00000074304 / NM_001134224.1; = p.R754Q on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as rs1231375445, COSV50789712; called by muse, mutect2, varscan2
- INPP4B | c.2517C>A p.F839L | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV53721386; called by muse, mutect2, varscan2
- IPO8 | c.2422C>A p.H808N | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56241039, COSV56242004, COSV56242337; called by muse, mutect2, varscan2
- IPO8 | c.853G>C p.E285Q | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV56241050, COSV56244690; called by muse, mutect2, varscan2
- IQCH | c.1985G>A p.R662Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs146418351, COSV60051732; called by muse, mutect2, varscan2
- IQSEC1 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as COSV56223400; called by muse, mutect2, varscan2
- IRAK1 | c.979C>T p.Q327* | Nonsense Mutation (SNP) | VAF 40/162 reads (25%) | catalogued as COSV57653368; called by muse, mutect2, varscan2
- ISYNA1 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.209); catalogued as rs751639570, COSV54210119; called by muse, mutect2, varscan2
- ITGB1BP2 | c.5C>G p.S2C | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV52137101; called by muse, mutect2, varscan2
- ITIH2 | c.481G>C p.D161H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1472119990, COSV64432870; called by muse, mutect2, varscan2
- ITPR2 | c.3740G>A p.R1247Q | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.55); PolyPhen benign (0.309); catalogued as rs775575901, COSV67268231; called by muse, mutect2, varscan2
- ITPRID2 | c.1854C>G p.I618M | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV57471116; called by muse, mutect2, varscan2
- ITSN1 | c.1687G>C p.D563H | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV66082665; called by muse, mutect2, varscan2
- ITSN2 | c.3362G>C p.R1121T | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV61946010; called by muse, mutect2, varscan2
- JDP2 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767954679, COSV50867820; called by muse, mutect2, varscan2
- KALRN | c.3984C>G p.I1328M | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV53770099, COSV53777397, COSV99564326; called by muse, mutect2, varscan2
- KALRN | c.4330G>A p.E1444K | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV99564329; called by muse, mutect2, varscan2
- KANK2 | c.1122G>C p.E374D | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV62007609; called by muse, mutect2, varscan2
- KANK2 | c.919C>T p.Q307* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as rs746940251, COSV62007619; called by muse, mutect2, varscan2
- KCND1 | c.37C>T p.R13W | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782455528, COSV54413725; called by muse, mutect2
- KCNG3 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60148857; called by muse, mutect2, varscan2
- KDM4B | c.2058C>G p.I686M | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV50216853; called by muse, mutect2
- KDM6A | c.2342C>A p.S781Y | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV65039316; called by muse, varscan2
- KHSRP | c.956C>G p.S319C | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101231189, COSV67920175; called by muse, mutect2
- KIAA0232 | c.4116G>C p.E1372D | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs780084406, COSV56924742; called by muse, mutect2, varscan2
- KIAA0513 | c.502G>C p.E168Q | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs564854975, COSV50741065; called by muse, mutect2, varscan2
- KIAA1109 | c.4064C>T p.S1355L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); catalogued as rs1000133230, COSV52669921; called by muse, mutect2, varscan2
- KIAA1109 | c.11608G>A p.E3870K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV52669944; called by muse, mutect2, varscan2
- KIAA1210 | c.3130A>C p.T1044P | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.336); catalogued as COSV68176796; called by muse, mutect2, varscan2
- KIAA2026 | c.189G>A p.M63I | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.006); catalogued as COSV52389111; called by muse, mutect2, varscan2
- KIDINS220 | c.1300G>C p.D434H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56752578; called by muse, mutect2
- KIF19 | c.2461G>A p.A821T | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV63429295; called by muse, mutect2, varscan2
- KIF26B | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63637886; called by muse, mutect2
- KIF6 | c.1360G>C p.E454Q | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.063); catalogued as COSV54675077, COSV99760442; called by muse, mutect2, varscan2
- KIF6 | c.565C>G p.L189V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.615); catalogued as COSV54675099; called by muse, mutect2, varscan2
- KIF7 | c.3218C>T p.S1073L | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51540758; called by muse, mutect2, varscan2
- KIRREL3 | c.1118C>G p.S373C | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV73105614; called by muse, mutect2, varscan2
- KIT | c.2135C>T p.S712F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.609); catalogued as COSV55397323; called by mutect2, varscan2
- KLHDC9 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63509510; called by muse, mutect2
- KLHL1 | c.787C>T p.L263F | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64771083; called by muse, mutect2, varscan2
- KLHL11 | c.2094G>A p.M698I | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV59861820; called by muse, mutect2, varscan2
- KLHL2 | c.1225G>C p.D409H | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56976246; called by muse, mutect2
- KLHL28 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as rs975498723, COSV61887949; called by muse, mutect2, varscan2
- KLHL36 | c.576G>C p.K192N | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV50718704; called by mutect2, varscan2
- KLHL4 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.748); catalogued as COSV64141562; called by muse, mutect2, varscan2
- KLHL42 | c.549G>C p.Q183H | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.707); catalogued as COSV67145822; called by muse, mutect2, varscan2
- KLHL9 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62921218, COSV62921483; called by muse, mutect2, varscan2
- KMT2A | c.9598G>C p.E3200Q | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV63284894; called by muse, mutect2, varscan2
- KMT2A | c.11356C>T p.R3786C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63284485; called by muse, mutect2, varscan2
- KMT2B | c.4904G>A p.R1635Q | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55859960; called by muse, mutect2, varscan2
- KMT2C | c.7258C>G p.L2420V | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.5); PolyPhen benign (0.035); catalogued as rs755908212, COSV51431184; called by muse, mutect2, varscan2
- KMT2E | c.4762C>G p.Q1588E | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); catalogued as COSV57572418; called by muse, mutect2, varscan2
- KNOP1 | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | catalogued as COSV54927670; called by muse, mutect2, varscan2
- KPNA2 | c.649G>C p.D217H | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as COSV57857399; called by muse, mutect2, varscan2
- KPNA3 | c.807G>C p.L269F | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV55504419; called by muse, mutect2, varscan2
- KRT10 | c.167C>G p.S56C | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV54089412, COSV54090578; called by muse, mutect2, varscan2
- KRT6B | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as rs751774991, COSV52883271, COSV99360540; called by muse, mutect2, varscan2
- KRTAP10-11 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs753732254, COSV58177668; called by muse, mutect2, varscan2
- KRTAP12-4 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as rs1555942083, COSV59959481; called by muse, mutect2, varscan2
- KTN1 | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68023248; called by muse, mutect2, varscan2
- LAG3 | c.799C>G p.P267A | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV99179938; called by muse, mutect2, varscan2
- LARGE1 | c.1972G>C p.E658Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1443560894, COSV61660696; called by muse, mutect2, varscan2
- LATS1 | c.3019C>T p.H1007Y | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53589866; called by muse, mutect2, varscan2
- LCA5 | c.1903G>C p.D635H | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV63971185; called by muse, mutect2, varscan2
- LDB1 | c.1117G>A p.E373K (on ENST00000425280 / NM_001321612.2; = p.E339K on NM_003893.5) | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.997); catalogued as rs531176307, COSV63288962; called by muse, varscan2
- LDB1 | c.1046G>A p.G349E (on ENST00000425280 / NM_001321612.2; = p.G315E on NM_003893.5) | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV63288973; called by muse, varscan2
- LDB1 | c.1045G>A p.G349R (on ENST00000425280 / NM_001321612.2; = p.G315R on NM_003893.5) | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV63288986, COSV63289645; called by muse, varscan2
- LIMA1 | c.1147C>G p.Q383E | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV57965159; called by muse, mutect2, varscan2
- LINS1 | c.1636G>C p.D546H | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV59078694; called by muse, mutect2, varscan2
- LMO7 | c.2633C>G p.S878* (on ENST00000357063; = p.S559* on NM_005358.5) | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV58534581; called by muse, mutect2, varscan2
- LMO7 | c.3820C>G p.L1274V (on ENST00000357063; = p.L955V on NM_005358.5) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.046); catalogued as COSV58534607; called by muse, mutect2, varscan2
- LRG1 | c.943C>G p.Q315E | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (0.96); PolyPhen benign (0.01); catalogued as COSV56703423, COSV56704802; called by muse, mutect2, varscan2
- LRIG1 | c.2463G>C p.K821N | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV56239234; called by muse, mutect2, varscan2
- LRP1 | c.63C>G p.I21M | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV54508862; called by muse, mutect2, varscan2
- LRP1B | c.8902G>C p.D2968H | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67209165; called by muse, mutect2, varscan2
- LRP6 | c.3229C>T p.Q1077* | Nonsense Mutation (SNP) | VAF 9/19 reads (47%) | catalogued as COSV99743344; called by muse, mutect2, varscan2
- LRP8 | c.1692G>C p.K564N | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60097868, COSV60101968; called by muse, mutect2, varscan2
- LRRC1 | c.1568C>T p.S523F | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV63828855; called by muse, mutect2, varscan2
- LRRC36 | c.1708C>T p.Q570* | Nonsense Mutation (SNP) | VAF 15/35 reads (43%) | catalogued as COSV52079219; called by muse, mutect2, varscan2
- LRRC37B | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs756146975, COSV58951953; called by muse, mutect2, varscan2
- LRRC43 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs757463217, COSV60289539; called by muse, mutect2, varscan2
- LRRC8B | c.2281G>A p.E761K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV58374455; called by muse, mutect2, varscan2
- LRRN1 | c.562G>C p.D188H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV60012957; called by muse, mutect2, varscan2
- LSAMP | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.166); catalogued as COSV61286231, COSV61287114; called by muse, mutect2, varscan2
- LSM6 | c.231G>C p.K77N | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.101); catalogued as COSV56852189; called by muse, mutect2
- LTBP3 | c.2896G>A p.E966K | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as COSV54212157; called by muse, mutect2, varscan2
- MADCAM1 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as COSV53128343; called by muse, mutect2, varscan2
- MAGEB3 | c.130C>G p.L44V | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.029); catalogued as COSV64396990; called by muse, mutect2, varscan2
- MAGEE1 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.073); catalogued as COSV63909853; called by muse, mutect2, varscan2
- MAGI3 | c.1254G>C p.M418I | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV56833745; called by muse, mutect2, varscan2
- MAK16 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV62452437; called by muse, mutect2, varscan2
- MAP2 | c.352G>C p.D118H | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52288527; called by mutect2, varscan2
- MAP3K12 | c.303G>A p.M101I | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV57232452; called by muse, mutect2, varscan2
- MAP3K14 | c.1630G>C p.D544H | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV60923390; called by muse, mutect2, varscan2
- MAPK8IP3 | c.845C>T p.S282L | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs777199250, COSV51719287; called by muse, mutect2, varscan2
- MAST3 | c.3886G>A p.E1296K | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as COSV53219813; called by muse, mutect2, varscan2
- MATK | c.133-1G>A p.X45_splice (on ENST00000310132 / NM_139355.3; = p.X46_splice on NM_002378.4) | Splice Site (SNP) | VAF 18/36 reads (50%) | catalogued as COSV59553996, COSV59554256; called by muse, mutect2, varscan2
- MBNL1 | c.83C>G p.S28* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | catalogued as COSV56830877; called by muse, mutect2, varscan2
- MCM3AP | c.2506G>T p.E836* | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as COSV52438948; called by muse, mutect2, varscan2
- MCUB | c.347-1G>C p.X116_splice | Splice Site (SNP) | VAF 11/36 reads (31%) | catalogued as COSV67119612; called by muse, mutect2, varscan2
- MED13 | c.5263G>A p.E1755K | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.578); catalogued as rs1469490643, COSV67263133, COSV67267094; called by muse, mutect2, varscan2
- MED13 | c.5113G>A p.E1705K | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as COSV67263134; called by muse, mutect2, varscan2
- MED13 | c.3619G>C p.D1207H | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.921); catalogued as COSV101180754, COSV67263138; called by muse, mutect2, varscan2
- MED13 | c.3390G>A p.M1130I | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV67263141; called by muse, mutect2, varscan2
- MED13 | c.3118G>C p.D1040H | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67263144; called by muse, mutect2, varscan2
- MEPCE | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52769072; called by muse, mutect2, varscan2
- METTL2A | c.575G>A p.G192E | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61044285; called by muse, mutect2, varscan2
- MEX3D | c.579G>C p.E193D | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66311985; called by muse, mutect2, varscan2
- MFAP1 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV51038742; called by muse, mutect2, varscan2
- MIA3 | c.2757G>C p.K919N | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.024); catalogued as COSV60512137; called by muse, mutect2
- MIA3 | c.4798G>A p.E1600K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as COSV100485023; called by muse, mutect2, varscan2
- MIIP | c.1047G>C p.Q349H | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.834); catalogued as COSV52427514; called by muse, mutect2, varscan2
- MKS1 | c.178C>A p.Q60K | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV100439615, COSV58303587; called by muse, mutect2, varscan2
- MMP16 | c.469G>C p.D157H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.191); catalogued as COSV54161178, COSV99685811; called by muse, mutect2, varscan2
- MOCOS | c.1637C>G p.S546C | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.149); catalogued as COSV54342754; called by muse, mutect2, varscan2
- MPHOSPH8 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as rs745974518, COSV64055292; called by muse, mutect2, varscan2
- MPP3 | c.1313C>T p.S438F | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV68197991; called by muse, mutect2, varscan2
- MRC2 | c.456G>C p.Q152H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); catalogued as rs779047023, COSV57638995; called by muse, mutect2, varscan2
- MRC2 | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as rs370162640; called by muse, mutect2, varscan2
- MRPL43 | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 21/48 reads (44%) | catalogued as COSV52967637; called by muse, mutect2, varscan2
- MRPS14 | c.199C>T p.L67F | Missense Mutation (SNP) | VAF 50/84 reads (60%) | SIFT tolerated (0.05); PolyPhen benign (0.321); catalogued as COSV62880231; called by muse, mutect2, varscan2
- MRPS18C | c.254C>G p.S85C | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV55024942; called by muse, mutect2, varscan2
- MS4A14 | c.480C>G p.F160L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV55734400; called by muse, mutect2, varscan2
- MSN | c.1304G>A p.R435Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.066); catalogued as rs371555667, COSV64303426, COSV64303855; called by muse, mutect2, varscan2
- MTDH | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV60346521; called by muse, mutect2, varscan2
- MTFR1 | c.439C>T p.L147F | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50951580; called by muse, mutect2, varscan2
- MTHFD2 | c.644C>T p.T215I | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV51201290; called by muse, mutect2, varscan2
- MUC13 | c.550G>C p.D184H | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.96); catalogued as COSV60699193; called by muse, mutect2, varscan2
- MUC4 | c.16238G>C p.*5413Sext*56 (on ENST00000463781 / NM_018406.7; = p.*1177Sext*56 on NM_004532.6) | Nonstop Mutation (SNP) | VAF 20/56 reads (36%) | catalogued as COSV57777546; called by muse, mutect2, varscan2
- MUC5B | c.11561C>A p.S3854Y | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.737); catalogued as rs755762113, COSV71591592; called by muse, mutect2, varscan2
- MUC5B | c.12812C>G p.S4271C | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV71591593; called by muse, mutect2, varscan2
- MUC5B | c.13148C>T p.S4383F | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV101500098, COSV71591597; called by muse, mutect2, varscan2
- MUL1 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1456100592, COSV51641509; called by muse, mutect2, varscan2
- MYF6 | c.683C>G p.S228W | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs201098963, COSV57351406, COSV57351420; called by muse, mutect2, varscan2
- MYH1 | c.5407G>A p.E1803K | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56847014; called by muse, mutect2, varscan2
- MYH10 | c.1441G>C p.E481Q | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as COSV52599570; called by muse, mutect2, varscan2
- MYH7 | c.1788G>C p.K596N | Missense Mutation (SNP) | VAF 57/102 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs606231325, COSV62518507; called by muse, mutect2, varscan2
- MYH7 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.358); catalogued as COSV100805883, COSV62518511; called by muse, mutect2, varscan2
- MYO16 | c.576G>C p.Q192H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV51789390; called by mutect2, varscan2
- MYO19 | c.2270G>A p.R757H (on ENST00000614623 / NM_001163735.1; = p.R557H on NM_025109.5) | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs776257543; called by muse, mutect2, varscan2
- MYO9A | c.2162G>A p.R721K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.262); catalogued as rs763470731, COSV61849988; called by muse, mutect2, varscan2
- MYOG | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV54095415; called by muse, mutect2, varscan2
- MYT1L | c.1594G>T p.D532Y | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67718132; called by muse, mutect2, varscan2
- NAA16 | c.2206G>A p.E736K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.573); catalogued as COSV65128140, COSV65128716; called by muse, mutect2, varscan2
- NAA25 | c.1540C>T p.R514* | Nonsense Mutation (SNP) | VAF 13/21 reads (62%) | catalogued as COSV55703099, COSV55705489; called by muse, mutect2, varscan2
- NAAA | c.796G>C p.D266H | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.587); catalogued as COSV54431997; called by muse, mutect2, varscan2
- NAIF1 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 17/41 reads (41%) | catalogued as COSV66090669, COSV66092563; called by muse, mutect2, varscan2
- NALCN | c.3599G>A p.R1200K | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV51931182; called by muse, mutect2, varscan2
- NAP1L3 | c.394C>G p.L132V | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59074929, COSV99054001; called by muse, mutect2, varscan2
- NAT8 | c.13C>G p.H5D | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV55542497; called by muse, mutect2, varscan2
- NAV2 | c.2440C>T p.R814W (on ENST00000396087 / NM_001244963.2; = p.R791W on NM_145117.5) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773530667, COSV100585355, COSV62320948; called by muse, mutect2, varscan2
- NCKAP1L | c.3020C>T p.S1007F | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV53203353; called by muse, mutect2, varscan2
- NDNF | c.99G>C p.Q33H | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs760205671, COSV65633225; called by muse, mutect2, varscan2
- NEFH | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV60216446, COSV60216593; called by muse, mutect2, varscan2
- NETO1 | c.1196G>C p.R399T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55005293; called by muse, mutect2, varscan2
- NFX1 | c.2350C>G p.H784D | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100582555, COSV59309747; called by muse, mutect2, varscan2
- NHLRC2 | c.1327G>C p.D443H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV65174717; called by muse, mutect2, varscan2
- NIPA2 | c.259C>G p.P87A | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61682558; called by muse, mutect2, varscan2
- NLRC5 | c.1102G>C p.D368H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52653855; called by muse, mutect2, varscan2
- NLRC5 | c.5378C>T p.P1793L | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1230550674, COSV99347327; called by muse, mutect2
- NLRP1 | c.3874G>T p.V1292L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV52564375; called by muse, mutect2, varscan2
- NLRP13 | c.2125G>C p.D709H | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV61621294; called by muse, mutect2, varscan2
- NLRP4 | c.1156G>T p.E386* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV56712322, COSV56720587; called by muse, varscan2
- NOC3L | c.1669C>T p.H557Y | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV64929843; called by muse, mutect2
- NODAL | c.792G>T p.W264C | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54660983; called by muse, mutect2, varscan2
- NOL11 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53523080, COSV99474928; called by muse, mutect2, varscan2
- NONO | c.997G>T p.E333* | Nonsense Mutation (SNP) | VAF 8/12 reads (67%) | catalogued as COSV52137094; called by muse, mutect2, varscan2
- NOTCH1 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs780325547, COSV53045503, COSV99492623; called by muse, mutect2, varscan2
- NOTCH4 | c.5792G>A p.R1931Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs752960355, COSV66680251; called by muse, mutect2, varscan2
- NPEPPS | c.153C>G p.F51L | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as rs746589578, COSV100444038, COSV59102024; called by muse, mutect2, varscan2
- NPR3 | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.717); catalogued as COSV54086734, COSV54090126; called by muse, mutect2, varscan2
- NPY4R | c.129C>A p.F43L | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.106); catalogued as COSV65397952, COSV65399230; called by muse, mutect2, varscan2
- NR2C1 | c.1429G>C p.E477Q | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as COSV58009466; called by muse, mutect2, varscan2
- NRG3 | c.1294G>T p.V432L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.023); catalogued as COSV100930362, COSV64557266; called by muse, mutect2, varscan2
- NSD3 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV57618197; called by muse, mutect2, varscan2
- NUDT19 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760397233, COSV67959441; called by muse, mutect2, varscan2
- NUP155 | c.2494G>C p.E832Q (on ENST00000231498 / NM_153485.3; = p.E773Q on NM_004298.4) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.74); catalogued as COSV51529213; called by muse, mutect2, varscan2
- NUP155 | c.1217C>G p.S406* (on ENST00000231498 / NM_153485.3; = p.S347* on NM_004298.4) | Nonsense Mutation (SNP) | VAF 27/63 reads (43%) | catalogued as COSV51529232; called by muse, mutect2, varscan2
- NUP210L | c.2884G>T p.E962* | Nonsense Mutation (SNP) | VAF 5/12 reads (42%) | catalogued as COSV55146153; called by muse, mutect2, varscan2
- NUP88 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52584523; called by muse, mutect2, varscan2
- NXF1 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as COSV53673580; called by muse, mutect2, varscan2
- NXF1 | c.34G>C p.D12H | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53673615; called by muse, varscan2
- NXT2 | c.55G>C p.E19Q (on ENST00000372106 / NM_001242617.2; = p.E74Q on NM_018698.5) | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as COSV54296505, COSV54296730; called by muse, mutect2, varscan2
- NXT2 | c.293G>T p.G98V (on ENST00000372106 / NM_001242617.2; = p.G153V on NM_018698.5) | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54296517; called by muse, mutect2, varscan2
- OAS2 | c.1403C>G p.S468C | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs755897997, COSV60802284; called by mutect2, varscan2
- OBSL1 | c.4924G>A p.E1642K | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as rs762255736, COSV54705290; called by muse, mutect2, varscan2
- OBSL1 | c.4567G>C p.E1523Q | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.932); catalogued as rs368547852, COSV54705310; called by muse, mutect2, varscan2
- ONECUT2 | c.950C>A p.S317* | Nonsense Mutation (SNP) | VAF 16/37 reads (43%) | catalogued as COSV101529727, COSV72203322; called by muse, mutect2, varscan2
- OPLAH | c.217C>T p.H73Y | Missense Mutation (SNP) | VAF 57/193 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV70677828; called by muse, mutect2, varscan2
- OPRM1 | c.1049G>T p.R350I | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV57675576; called by muse, mutect2, varscan2
- OR4L1 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.085); catalogued as COSV59851066; called by muse, varscan2
- OR51D1 | c.573C>A p.F191L | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV62914108; called by muse, mutect2, varscan2
- OR52A5 | c.856G>A p.V286I | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.734); catalogued as COSV56614096, COSV56614951; called by muse, mutect2, varscan2
- OR5AN1 | c.756C>A p.F252L | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV58321568; called by muse, mutect2, varscan2
- OR8B8 | c.658C>G p.L220V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); catalogued as rs763623932, COSV60144397; called by muse, mutect2, varscan2
- OR8D1 | c.160C>G p.L54V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV63442086; called by muse, mutect2, varscan2
- OSBPL5 | c.2058G>C p.E686D | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs1158002740, COSV55141188; called by muse, mutect2, varscan2
- OTUD7B | c.1255G>C p.E419Q | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV64915968; called by muse, mutect2, varscan2
- OXGR1 | c.528C>G p.N176K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.033); catalogued as COSV53657410; called by muse, mutect2, varscan2
- P2RY1 | c.495G>C p.K165N | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.697); catalogued as rs1454794599, COSV59309323; called by muse, mutect2, varscan2
- PAIP1 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV100166461, COSV59085808; called by muse, mutect2, varscan2
- PALLD | c.2809C>G p.L937V (on ENST00000505667 / NM_001166108.2; = p.L920V on NM_016081.4) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.883); catalogued as COSV54978956; called by muse, mutect2, varscan2
- PAPOLA | c.1886C>T p.S629L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.22); catalogued as COSV99354243; called by muse, mutect2
- PAPPA2 | c.1441C>T p.L481F | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV62776761, COSV62776919; called by muse, mutect2, varscan2
- PATJ | c.2529G>C p.E843D | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV57160537; called by muse, mutect2, varscan2
- PAX4 | c.625C>G p.L209V | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58388340; called by muse, mutect2, varscan2
- PCDH15 | c.4097G>C p.R1366T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.179); catalogued as COSV57296774; called by muse, mutect2, varscan2
- PCDHB10 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53378016; called by muse, mutect2
- PCDHGA3 | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53933408; called by muse, mutect2, varscan2
- PCM1 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61515882; called by muse, mutect2, varscan2
- PCM1 | c.2129C>G p.S710* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as rs1174077977, COSV61515888; called by muse, mutect2, varscan2
- PDE1A | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1321620913, COSV59521328; called by muse, mutect2, varscan2
- PDE3A | c.2409C>G p.F803L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0.014); catalogued as COSV62971507; called by muse, mutect2, varscan2
- PDGFRA | c.1881G>C p.K627N | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57267281; called by muse, mutect2, varscan2
- PDRG1 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV52431283; called by muse, mutect2, varscan2
- PDZRN4 | c.1537G>A p.E513K (on ENST00000402685 / NM_001164595.2; = p.E255K on NM_013377.4) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs1172695091, COSV54199032, COSV54216054; called by muse, mutect2, varscan2
- PER1 | c.1654G>A p.D552N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.98); catalogued as rs765783851, COSV57918957; called by muse, mutect2, varscan2
- PFKFB2 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 25/162 reads (15%) | PolyPhen benign (0.022); catalogued as COSV65547887; called by muse, mutect2, varscan2
- PGAP6 | c.1751C>T p.S584F | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771178017, COSV51738889; called by muse, mutect2, varscan2
- PGBD1 | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 60/69 reads (87%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.009); catalogued as COSV52552727; called by muse, mutect2, varscan2
- PGLYRP1 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs760540043, COSV50516401; called by muse, mutect2, varscan2
- PGM5 | c.1341G>A p.M447I | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as COSV67167437; called by muse, mutect2, varscan2
- PHETA2 | c.274G>C p.D92H | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV58790830; called by muse, mutect2, varscan2
- PHF20 | c.1433G>T p.G478V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV59185702; called by mutect2, varscan2
- PHF20L1 | c.2020G>T p.E674* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV55189836, COSV55191645; called by muse, mutect2, varscan2
- PHF8 | c.2312C>T p.S771L (on ENST00000357988 / NM_001184896.1; = p.S735L on NM_015107.3) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.758); catalogued as rs377130882, COSV57677953; called by muse, mutect2, varscan2
- PHLPP1 | c.4276G>C p.E1426Q | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.433); catalogued as COSV53024006, COSV53027160; called by muse, mutect2, varscan2
- PHTF1 | c.702G>C p.K234N | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.704); catalogued as COSV63367327; called by muse, mutect2, varscan2
- PIK3C2A | c.752C>T p.S251L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.023); catalogued as COSV56402045; called by muse, mutect2, varscan2
- PIK3C2A | c.619C>A p.H207N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.028); catalogued as COSV56402052; called by muse, mutect2, varscan2
- PIK3CB | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.326); catalogued as COSV56685338; called by muse, mutect2, varscan2
- PIK3CB | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV56685345; called by muse, varscan2
- PIRT | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.801); catalogued as COSV74119879; called by muse, mutect2, varscan2
- PJVK | c.432G>C p.L144F | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as COSV57869959; called by muse, mutect2
- PKNOX1 | c.321C>G p.F107L | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.97); catalogued as COSV52335582; called by muse, mutect2
- PKP2 | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as rs727505312, CD094105, COSV50729409; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLAC1 | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 25/124 reads (20%) | catalogued as COSV63655636; called by muse, mutect2, varscan2
- PLAT | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as rs1055213581, COSV54274900; called by muse, mutect2, varscan2
- PLCB1 | c.970C>G p.H324D | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as COSV62047639; called by muse, mutect2, varscan2
- PLCE1 | c.5855G>C p.R1952T | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53347339; called by muse, mutect2
- PLCG1 | c.1948G>C p.E650Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.219); catalogued as COSV54817804; called by muse, mutect2, varscan2
- PLCH1 | c.5047G>A p.D1683N (on ENST00000340059 / NM_001130960.2; = p.D1675N on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.494); catalogued as rs866009964, COSV58194220; called by muse, mutect2, varscan2
- PLCH1 | c.4618G>A p.D1540N (on ENST00000340059 / NM_001130960.2; = p.D1532N on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV58194244, COSV58196586; called by muse, mutect2, varscan2
- PLCH1 | c.4255G>A p.E1419K (on ENST00000340059 / NM_001130960.2; = p.E1411K on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.115); catalogued as COSV58194261; called by muse, mutect2, varscan2
- PLCH1 | c.4039G>A p.D1347N (on ENST00000340059 / NM_001130960.2; = p.D1339N on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV58194289; called by muse, mutect2, varscan2
- PLCH1 | c.3455C>T p.S1152F (on ENST00000340059 / NM_001130960.2; = p.S1144F on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); catalogued as COSV58194305; called by muse, mutect2, varscan2
- PLEKHA1 | c.615G>A p.M205I | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); catalogued as COSV64569295; called by muse, varscan2
- PLIN4 | c.171G>C p.Q57H (on ENST00000301286; = p.Q72H on NM_001367868.2) | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.431); catalogued as COSV56690403; called by muse, mutect2, varscan2
- PNMA2 | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 10/16 reads (63%) | catalogued as rs200050472, COSV72908505; called by muse, mutect2, varscan2
- POLQ | c.6358C>G p.L2120V | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1318200060, COSV51750212; called by muse, mutect2, varscan2
- POLR1C | c.190G>C p.D64H | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54829414; called by muse, mutect2, varscan2
- POMZP3 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 57/74 reads (77%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.636); catalogued as COSV51886281, COSV99300545; called by muse, mutect2, varscan2
- PPARGC1A | c.664C>T p.H222Y | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.388); catalogued as COSV53524134, COSV53526922; called by muse, mutect2, varscan2
- PPFIBP2 | c.2321G>A p.R774K | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754953889, COSV55076377; called by muse, mutect2, varscan2
- PPM1E | c.1130G>C p.R377T | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57572495, COSV57573258; called by muse, mutect2, varscan2
- PPP1R12A | c.2143C>T p.R715C | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV54107662; called by muse, mutect2, varscan2
- PPP1R13B | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | catalogued as COSV52450783; called by muse, mutect2, varscan2
- PPP1R9B | c.144G>C p.K48N | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.362); catalogued as COSV57541147; called by muse, mutect2, varscan2
- PPP2R2B | c.925C>G p.L309V (on ENST00000394409; = p.L375V on NM_181674.2) | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV60762900; called by muse, mutect2, varscan2
- PPP2R5B | c.594C>A p.L198= | Splice Region (SNP) | VAF 16/37 reads (43%) | catalogued as COSV51210148; called by muse, mutect2, varscan2
- PPP2R5C | c.1057G>C p.E353Q | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58270319; called by muse, mutect2, varscan2
- PPP4R3A | c.2071G>C p.E691Q (on ENST00000554943 / NM_001366432.1; = p.E678Q on NM_001284280.1) | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.299); catalogued as COSV61504265; called by muse, mutect2, varscan2
- PPP6R1 | c.2116C>T p.Q706* | Nonsense Mutation (SNP) | VAF 19/70 reads (27%) | catalogued as COSV58984003; called by muse, mutect2, varscan2
- PPT1 | c.301G>T p.D101Y (on ENST00000433473; = p.D102Y on NM_000310.4) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65655577; called by muse, mutect2
- PRAMEF19 | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 29/296 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as rs761781565; called by muse, mutect2
- PRB2 | c.1132C>T p.Q378* | Nonsense Mutation (SNP) | VAF 30/127 reads (24%) | catalogued as rs1266876580, COSV66982873; called by muse, mutect2, varscan2
- PRDM5 | c.458C>G p.S153* | Nonsense Mutation (SNP) | VAF 22/51 reads (43%) | catalogued as COSV53359272; called by muse, mutect2, varscan2
- PRKCI | c.318C>G p.F106L | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV55518077; called by muse, mutect2, varscan2
- PRKD1 | c.2548G>C p.E850Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as COSV59566313; called by muse, mutect2, varscan2
- PRLR | c.1750G>C p.E584Q | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51494985; called by muse, mutect2, varscan2
- PROCR | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs900068008, COSV53825667; called by muse, mutect2
- PROS1 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV62398262; called by muse, mutect2, varscan2
- PRPF6 | c.2505G>C p.K835N | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.317); catalogued as COSV53869322; called by muse, mutect2, varscan2
- PRPSAP2 | c.949G>C p.E317Q | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.115); catalogued as COSV52065449; called by muse, mutect2, varscan2
- PRRC2A | c.1920G>T p.Q640H | Missense Mutation (SNP) | VAF 46/55 reads (84%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV101051340, COSV65686185; called by muse, mutect2, varscan2
- PRRC2A | c.2529G>C p.E843D | Missense Mutation (SNP) | VAF 25/27 reads (93%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.755); catalogued as COSV65686189; called by muse, mutect2, varscan2
- PRRC2B | c.3623G>A p.R1208Q | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1404858531, COSV61936200; called by muse, mutect2, varscan2
- PRSS1 | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 25/61 reads (41%) | catalogued as CM011001, COSV61192517; called by muse, mutect2, varscan2
- PRSS53 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs754932389, COSV54923894; called by muse, mutect2, varscan2
- PRUNE2 | c.5101G>C p.E1701Q | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV65040737; called by muse, mutect2, varscan2
- PSD | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs777864461, COSV50045031; called by muse, mutect2, varscan2
- PSG8 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as rs140231543; called by muse, mutect2, varscan2
- PSMD4 | c.112C>T p.H38Y | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.516); catalogued as COSV64393319, COSV64393707; called by muse, mutect2, varscan2
- PSPN | c.154C>T p.H52Y | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs1165162040, COSV55532105; called by muse, mutect2, varscan2
- PTCH2 | c.2777C>T p.A926V | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.734); catalogued as COSV64710802; called by muse, mutect2, varscan2
- PTCHD1 | c.800T>A p.V267E | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs1359131084, COSV65059821; called by muse, mutect2, varscan2
- PTMA | c.148G>C p.D50H (on ENST00000341369 / NM_001099285.2; = p.D49H on NM_002823.5) | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.553); catalogued as COSV100398383; called by muse, mutect2
- PTPRO | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.01); catalogued as rs763453061, COSV55508582; called by muse, mutect2, varscan2
- PTPRO | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs724159880, COSV55504336, COSV55504926; called by muse, mutect2
- PTPRU | c.3851C>T p.S1284F | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.999); catalogued as COSV60526404; called by muse, mutect2, varscan2
- PURG | c.191G>C p.R64P | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.727); catalogued as COSV53299171; called by muse, mutect2, varscan2
- PZP | c.1967C>G p.S656* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as COSV54358833; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1706C>T p.S569F | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV54759497; called by muse, mutect2, varscan2
- RAB12 | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV61398395; called by muse, mutect2, varscan2
- RABGAP1 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.268); catalogued as COSV58060072; called by muse, mutect2, varscan2
- RACGAP1 | c.452C>A p.S151Y | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as COSV56699105; called by muse, mutect2, varscan2
- RAD23B | c.325C>T p.Q109* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV63658207; called by muse, mutect2
- RAD51 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.072); catalogued as COSV99139239; called by muse, varscan2
- RAD51C | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.02); catalogued as COSV53621036, COSV99541195; called by muse, mutect2
- RAD9B | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as rs1456277934, COSV63777715; called by muse, mutect2, varscan2
- RAI14 | c.1902G>A p.M634I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV54293158; called by muse, mutect2
- RALA | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.562); catalogued as COSV50049109; called by muse, mutect2, varscan2
- RANBP10 | c.373C>G p.Q125E | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV58157238; called by muse, mutect2, varscan2
- RANBP2 | c.4100C>T p.S1367L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV51697115; called by muse, mutect2, varscan2
- RANBP3 | c.733G>C p.E245Q (on ENST00000340578 / NM_007322.3; = p.E240Q on NM_003624.3) | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as COSV50381218; called by muse, mutect2, varscan2
- RARS2 | c.338G>C p.G113A | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV65760938, COSV65762421; called by muse, mutect2, varscan2
- RASSF4 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58485859, COSV58489505; called by muse, mutect2, varscan2
- RASSF9 | c.1261C>G p.Q421E | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746945008, COSV63433303; called by muse, mutect2, varscan2
- RB1 | c.585G>T p.W195C | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57297743, COSV57301309, COSV57304210; called by muse, mutect2, varscan2
- RBBP8NL | c.39G>C p.E13D | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53348919; called by muse, mutect2, varscan2
- RBM10 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1556777452, COSV61308730; called by muse, mutect2, varscan2
- RBM11 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 7/13 reads (54%) | catalogued as rs1189713203, COSV68748060; called by muse, mutect2, varscan2
- RBM17 | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as COSV65913863, COSV65914599; called by muse, mutect2, varscan2
- RBM33 | c.2180C>G p.S727C | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1176500242, COSV56629366; called by muse, mutect2, varscan2
- RBM45 | c.607G>C p.D203H | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV53720665; called by muse, mutect2, varscan2
- RBM5 | c.273C>G p.I91M | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.496); catalogued as COSV100762298, COSV61738296; called by muse, mutect2, varscan2
- RBX1 | c.81G>C p.W27C | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53430032; called by muse, mutect2, varscan2
- RDH8 | c.631G>A p.E211K (on ENST00000651512; = p.E191K on NM_015725.4) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.103); catalogued as rs142734308; called by muse, mutect2, varscan2
- RELA | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58013853, COSV58014500; called by muse, mutect2, varscan2
- RERE | c.104C>G p.S35* | Nonsense Mutation (SNP) | VAF 30/76 reads (39%) | catalogued as COSV61941121; called by muse, mutect2, varscan2
- RESF1 | c.5137G>C p.E1713Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV57019740; called by muse, mutect2
- REV3L | c.8579G>C p.R2860T | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62618129; called by muse, mutect2, varscan2
- RFPL4B | c.340C>G p.L114V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as COSV71437304; called by muse, mutect2, varscan2
- RGS20 | c.1003G>C p.E335Q (on ENST00000297313 / NM_170587.4; = p.E188Q on NM_003702.4) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV52016126; called by muse, mutect2, varscan2
- RGS4 | c.607C>T p.Q203* | Nonsense Mutation (SNP) | VAF 44/75 reads (59%) | catalogued as COSV63357089; called by muse, mutect2, varscan2
- RHCE | c.851C>A p.S284* | Nonsense Mutation (SNP) | VAF 26/127 reads (20%) | catalogued as COSV53799752, COSV53803958, COSV99604527; called by muse, mutect2, varscan2
- RIC8A | c.1381G>T p.E461* (on ENST00000526104 / NM_001286134.1; = p.E467* on NM_021932.5) | Nonsense Mutation (SNP) | VAF 14/65 reads (22%) | catalogued as COSV57342568; called by muse, mutect2, varscan2
- RIT1 | c.102G>C p.K34N | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64166492; called by muse, mutect2
- RNF125 | c.336G>T p.M112I | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.838); catalogued as CM1412055, COSV54184308; called by muse, mutect2, varscan2
- RNF146 | c.899C>G p.S300C (on ENST00000368314 / NM_001242850.2; = p.S299C on NM_030963.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV58932287; called by mutect2, varscan2
- RNF151 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as rs767230051, COSV58399725; called by muse, mutect2, varscan2
- RNF213 | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV60622479; called by muse, mutect2, varscan2
- RNF213 | c.10795C>T p.H3599Y | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60395569; called by muse, mutect2, varscan2
- RNF41 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61504302; called by muse, mutect2, varscan2
- RNPEPL1 | c.1600G>C p.E534Q | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.891); catalogued as COSV54372425; called by muse, mutect2, varscan2
- ROS1 | c.5114C>T p.S1705L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV63851375, COSV63859753; called by muse, varscan2
- RP1L1 | c.5464G>A p.G1822S | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as rs1362790147, COSV66754249; called by muse, mutect2, varscan2
- RPGR | c.2584G>A p.E862K (on ENST00000339363 / NM_001367249.1; = p.E657K on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.269); catalogued as COSV58834564; called by muse, mutect2, varscan2
- RPS6KA3 | c.946G>C p.D316H | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.841); catalogued as COSV101084393; called by muse, mutect2
- RPS6KA5 | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.885); catalogued as COSV100002635, COSV56221500; called by muse, mutect2, varscan2
- RSL24D1 | c.26G>C p.C9S | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as rs1218707788, COSV53065424; called by muse, mutect2
- RTN2 | c.59C>G p.S20* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV55593632; called by muse, mutect2, varscan2
- SACS | c.4159C>T p.P1387S | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.156); catalogued as COSV66538724; called by muse, mutect2, varscan2
- SALL4 | c.36C>G p.I12M | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs777241507, COSV53851679; called by muse, mutect2
- SARDH | c.1326C>T p.I442= | Splice Region (SNP) | VAF 16/57 reads (28%) | catalogued as COSV64104412; called by muse, mutect2, varscan2
- SARM1 | c.1558G>C p.E520Q | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV50229371; called by muse, mutect2, varscan2
- SBF2 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56297297; called by muse, mutect2, varscan2
- SCFD2 | c.730C>G p.Q244E | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV66371029, COSV66371776; called by muse, mutect2, varscan2
- SCN4A | c.3301G>C p.D1101H | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV71126546, COSV71129014; called by muse, mutect2, varscan2
- SCN8A | c.3472G>C p.D1158H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV100633833, COSV61978293; called by muse, mutect2, varscan2
- SCRIB | c.2176G>C p.E726Q | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV57585679; called by muse, mutect2, varscan2
- SDAD1 | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as rs778848101, COSV62402636; called by muse, mutect2, varscan2
- SDHA | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 45/185 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs199615452, COSV53767427; called by muse, mutect2, varscan2
- SEC23B | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.405); catalogued as COSV52719838; called by muse, mutect2, varscan2
- SEPTIN12 | c.688G>T p.E230* | Nonsense Mutation (SNP) | VAF 17/59 reads (29%) | catalogued as COSV51616646; called by muse, mutect2, varscan2
- SEPTIN3 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52171783; called by muse, mutect2, varscan2
- SERPINA12 | c.679G>C p.D227H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); catalogued as COSV100369689; called by muse, mutect2, varscan2
- SERTAD4 | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.36); catalogued as COSV65399218; called by muse, mutect2, varscan2
- SETD2 | c.3752C>T p.S1251L | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as rs1559742482, COSV57435811, COSV57439483; called by muse, mutect2, varscan2
- SH2B1 | c.971C>G p.S324C | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.331); catalogued as COSV59462342; called by muse, mutect2, varscan2
- SH3GLB1 | c.254G>C p.R85T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV65279719; called by muse, mutect2, varscan2
- SHANK1 | c.6322G>C p.E2108Q | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.534); catalogued as COSV53248374; called by muse, mutect2
- SHCBP1L | c.1532G>A p.C511Y | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762720953, COSV62354598; called by muse, mutect2, varscan2
- SHLD2 | c.610C>T p.H204Y | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs1420719941, COSV53954361; called by muse, mutect2, varscan2
- SHROOM3 | c.263G>C p.R88T | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56027794; called by muse, mutect2, varscan2
- SIN3A | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV64582583; called by muse, mutect2, varscan2
- SIPA1L2 | c.2732A>G p.K911R | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.638); catalogued as COSV53388967; called by muse, mutect2, varscan2
- SIPA1L3 | c.1563G>C p.E521D | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV55912728, COSV55923765; called by muse, mutect2, varscan2
- SLC13A1 | c.225G>C p.K75N | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV52010450; called by muse, mutect2, varscan2
- SLC13A5 | c.1699G>C p.E567Q | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.054); catalogued as COSV53422692; called by muse, mutect2, varscan2
- SLC16A11 | c.811G>C p.D271H (on ENST00000308009; = p.D247H on NM_153357.3) | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.411); catalogued as rs1220701932, COSV57274124; called by muse, mutect2, varscan2
- SLC17A2 | c.967G>C p.A323P | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as COSV55351626; called by muse, mutect2, varscan2
- SLC22A15 | c.939C>A p.F313L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.16); catalogued as COSV65677825; called by muse, mutect2, varscan2
- SLC25A18 | c.421C>G p.Q141E | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.065); catalogued as COSV53657544; called by muse, mutect2, varscan2
644 further variants in this file (244 protein-altering or splice-affecting, 363 silent, 37 other) are not listed here.
